Gene-level copy-number profile of specimen HCM-BROD-1124-C16-85B from HCMI case HCM-BROD-1124-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen HCM-BROD-1124-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd588f7c-db0e-4475-ad96-e1ac404f2ddc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1124-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/edda3d2e-980b-48e0-be80-95d7eb79aa21

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 544; copy number 2: 43; copy number 3: 9,871; copy number 4: 1,980; copy number 5: 24,862; copy number 6: 12,298; copy number 7: 4,301; copy number 8: 2,155; copy number 9: 1,882; copy number 10: 183; copy number 11: 175; copy number 12: 179; copy number 15: 295; copy number 16: 37; copy number 21: 55; copy number 24: 9; copy number 27: 6; copy number 63: 9; copy number 93: 14.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–26,118,408, 85 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 779 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,499,710–44,553,281, 87 genes, copy number 12–15 (broad region; genes not listed).
- chr7:38,269,491–38,300,322, 6 genes, copy number 27 (within-gene range 10–27): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:142,760,415–142,763,943, 1 gene, copy number 16 (within-gene range 9–16): PRSS3P1.
- chr12:23,529,504–24,562,544, 1 gene, copy number 24 (within-gene range 3–24): SOX5.
- chr12:24,212,421–27,502,185, 67 genes, copy number 16–93 (broad region; genes not listed).
- chr12:112,125,538–113,480,624, 37 genes, copy number 11: TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11, RPH3A, MIR1302-1, OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1.
- chr14:22,112,347–22,497,718, 54 genes, copy number 21: TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 21: TRAC.
- chr16:6,873,899–18,562,211, 278 genes, copy number 15 (broad region; genes not listed).
- chr16:19,501,693–19,522,123, 1 gene, copy number 11 (within-gene range 9–11): GDE1.
- chr16:19,523,811–19,886,167, 9 genes, copy number 11: CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B.
- chr20:55,504,906–58,850,903, 72 genes, copy number 11 (within-gene range 10–11) (broad region; genes not listed).
- chr20:59,300,443–64,327,972, 165 genes, copy number 11–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
